Gene-level copy-number profile of tumor specimen TCGA-VS-A9UD-01A from TCGA case TCGA-VS-A9UD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 73.4 years (26,815 days).
Specimen TCGA-VS-A9UD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.747b908f-87ff-4be9-82d0-931ac1b3cea6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9UD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ab38a251-09ff-47c6-b158-cf0acab8d8dc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,987; copy number 2: 15,599; copy number 3: 8,952; copy number 4: 22,911; copy number 5: 6,607; copy number 6: 3,200; copy number 7: 21; copy number 8: 20; copy number 10: 290; copy number 12: 190; copy number 18: 10; copy number 27: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9UD-01A-11D-A42N-01): tumor purity 0.6, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:86,668,507–86,756,298, 2 genes: LDB3, AC067750.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 519 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:74,274,234–78,187,233, 190 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).
- chr18:3,025,069–15,330,282, 308 genes, copy number 10–27 (broad region; genes not listed).
- chr19:3,314,403–3,700,468, 21 genes, copy number 10–18 (within-gene range 2–18): NFIC, AC007792.1, AC005514.1, SMIM24, AC005551.1, DOHH, FZR1, AC005787.1, MFSD12, C19orf71, AC005786.3, AC005786.2, AC005786.4, AC005786.1, HMG20B, GIPC3, TBXA2R, CACTIN-AS1, CACTIN, PIP5K1C, AC004637.1.

Autosomal genes at a single copy (total copy number 1): 1,987. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
